TCGA case TCGA-WC-A87W — Uveal Melanoma (TCGA-UVM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Nevi and Melanomas; Primary site: Eye and adnexa; Tissue source site: MD Anderson. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/60d7b6cf-d605-4837-9061-612f6bbb7393

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 57 years; Vital status: Alive.

Diagnoses (3)
1. Spindle cell melanoma, NOS (the primary disease): ICD-O-3 morphology code: 8772/3; ICD-10 code: C69.30; Tissue or organ of origin: Choroid; Site of resection or biopsy: Choroid; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 57.1 years (20,872 days); Year of diagnosis: 2010; Method of diagnosis: Enucleation; AJCC staging edition: 7th; AJCC clinical T: T2; AJCC clinical N: N0; AJCC clinical M: M0; AJCC clinical stage: Stage IIA; AJCC pathologic T: T2a; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIA; Metastasis at diagnosis: No Metastasis; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 1,703 days (4.7 years); Sites of involvement: Eye, Choroid.
   Pathology details: Measurement type: Pathologic; Tumor basal diameter: 13.
   Pathology details: Consistent pathology review: Yes; Extrascleral extension present: No; Measurement type: Pathologic; Spindle cell percent range: >90%; Tumor depth measurement: 5; Tumor shape: Dome.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Basal cell carcinoma, NOS: ICD-O-3 morphology code: 8090/3; Tissue or organ of origin: Skin, NOS; Classification of tumor: Subsequent Primary; Age at diagnosis: 58.8 years (21,478 days); Days to diagnosis: 606 days (1.7 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 625 days (1.7 years).
   Recorded as not given: Pharmaceutical Therapy, NOS, for initial diagnosis; Radiation Therapy, NOS, for initial diagnosis.
3. Subsequent primary of the skin of other and unspecified parts of face (histology not recorded by GDC). Age at diagnosis: 58.9 years (21,497 days); Days to diagnosis: 625 days (1.7 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis.
   Recorded as not given: Pharmaceutical Therapy, NOS, for initial diagnosis.

Follow-up (3 entries)
- Days to follow up: 977 days (2.7 years); Disease response: Tumor Free.
- Days to follow up: 1,386 days (3.8 years); Disease response: Tumor Free.
- Days to follow up: 1,703 days (4.7 years); Disease response: Tumor Free.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 90.3 kg; Height: 158 cm; BMI: 36.2.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-WC-A87W-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 10 mg.
  Slide TCGA-WC-A87W-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-WC-A87W-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-WC-A87W-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; New tumor event diagnosis indicator: Yes.
- Primary pathology, Tumor morphology list, Tumor morphology: Histologic diagnosis: Spindle Cell; Tumor morphology percentage: >90%.
- Primary pathology, Gene expression profile list: Gene expression profile: Class 1.
- Primary pathology: Tumor basal diameter mx: Pathologic Measurement; Tumor thickness: 5 mm; Tumor thickness measurement: Pathologic Measurement.
- New tumor event: New tumor event type: New Primary Tumor; New tumor event site: Skin; New tumor event histology: Basal Cell Carcinoma; New tumor event surgery: Yes; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: No.
- Follow-up form 1: Lost to follow-up: No; Tumor status: Tumor free; New tumor event diagnosis indicator: Yes.
- Follow-up form 1, New tumor event: New tumor event type: New Primary Tumor; New tumor event site other: left nasofacial sulcus; New tumor event surgery: Yes; New tumor event pharmaceutical treatment: No.
- Follow-up form 2: Lost to follow-up: No; Tumor status: Tumor free; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,703 days; disease-specific survival: no event (censored), 1,703 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 606 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-WC-A87W-01A-11D-A39V-01): tumor purity 0.98, ploidy 1.93, whole-genome doublings 0.
